Somatic mutation profile of tumor specimen ALCH-B2NM-TTP1-A (aliquot ALCH-B2NM-TTP1-A-1-0-D-A77Z-36) from ALCHEMIST case ALCH-B2NM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.9 years (27,705 days).
Specimen ALCH-B2NM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5014b9ec-cf6a-4202-9f64-2e3203a8e526.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2NM-NB1-A (Blood Derived Normal), aliquot ALCH-B2NM-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e50562e6-50d8-4ca4-b8f0-f2d15e2bb3fb

The open-access MAF lists 350 somatic variants for this specimen: 239 protein-altering or splice-affecting, 68 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 203, Silent 68, Intron 24, Nonsense Mutation 16, Frame Shift Del 8, RNA 5, 3'UTR 5, Splice Site 4, Frame Shift Ins 4, 5'Flank 4, 5'UTR 3, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 190/608 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by mutect2, varscan2
- TP53 | c.796G>C p.G266R | Missense Mutation (SNP) | VAF 191/623 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 86/250 reads (34%) | catalogued as rs1567556752, CM120852, COSV52811974, COSV52991347; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM7 | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51534609; called by muse, mutect2, varscan2
- ADCY7 | c.1699G>C p.D567H | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV54266306; called by muse, mutect2, varscan2
- AGAP2 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 24/169 reads (14%) | catalogued as rs1555199972; called by muse, mutect2, varscan2
- ARSJ | c.1771A>G p.T591A | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs1263160600; called by muse, mutect2, varscan2
- C5AR2 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs771555144, COSV57257522; called by muse, mutect2, varscan2
- CABP5 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs944693390; called by muse, mutect2, varscan2
- CCDC168 | c.5405C>A p.S1802* | Nonsense Mutation (SNP) | VAF 21/101 reads (21%) | catalogued as COSV70554826; called by muse, mutect2, varscan2
- CCDC39 | c.2291T>C p.I764T | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs372308915; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH18 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 72/341 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as COSV56913618; called by muse, mutect2, varscan2
- CENPF | c.7594C>G p.Q2532E | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100871640, COSV65273291; called by muse, mutect2, varscan2
- CLCN6 | c.88-1G>T p.X30_splice | Splice Site (SNP) | VAF 52/114 reads (46%) | catalogued as COSV56743505; called by muse, mutect2, varscan2
- COL19A1 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138486301; called by muse, mutect2, varscan2
- COLEC12 | c.1968del p.K656Nfs*4 | Frame Shift Del (DEL) | VAF 92/348 reads (26%) | catalogued as COSV101232229; called by mutect2, pindel, varscan2
- CR1 | c.3404C>T p.P1135L | Missense Mutation (SNP) | VAF 135/430 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.356); catalogued as rs770561116, COSV100888121; called by mutect2, varscan2
- CRPPA | c.982C>T p.Q328* (on ENST00000407010 / NM_001368197.1; = p.Q278* on NM_001101417.4) | Nonsense Mutation (SNP) | VAF 34/268 reads (13%) | catalogued as COSV101235313; called by muse, mutect2, varscan2
- CYP11B1 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 238/698 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as rs771177845; called by muse, mutect2, varscan2
- DLGAP2 | c.1032G>C p.K344N | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1320735829; called by muse, mutect2, varscan2
- DMD | c.7244G>T p.R2415L | Missense Mutation (SNP) | VAF 157/278 reads (56%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV58899961; called by muse, mutect2, varscan2
- DSG1 | c.1399A>G p.I467V | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.241); catalogued as CD090805; called by muse, mutect2, varscan2
- EPHA8 | c.2650C>A p.R884S | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as COSV51272991, COSV99385718; called by muse, mutect2, varscan2
- FASLG | c.780C>A p.N260K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60680319; called by muse, mutect2, varscan2
- FIGNL1 | c.508C>G p.R170G | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs748147882, COSV100794844; called by muse, mutect2, varscan2
- FLNC | c.5389G>A p.E1797K | Missense Mutation (SNP) | VAF 151/399 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as COSV100368955; called by muse, mutect2, varscan2
- FOXD4L4 | c.158A>T p.Q53L | Missense Mutation (SNP) | VAF 121/1542 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.258); catalogued as rs1325161982; called by muse, mutect2
- FPR2 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 98/293 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.298); catalogued as rs144552448; called by muse, mutect2, varscan2
- FRG2 | c.293G>C p.R98T | Missense Mutation (SNP) | VAF 107/596 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV66459875; called by muse, mutect2, varscan2
- GK2 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV62626028; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1729C>A p.Q577K | Missense Mutation (SNP) | VAF 72/658 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as rs1314524903, COSV71180866; called by mutect2, varscan2
- ITPR1 | c.2701G>T p.V901L (on ENST00000354582; = p.V886L on NM_002222.7) | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV56995830; called by muse, mutect2, varscan2
- KALRN | c.1515C>A p.H505Q | Missense Mutation (SNP) | VAF 190/642 reads (30%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV53779882; called by muse, mutect2, varscan2
- KIAA1109 | c.3700G>C p.E1234Q | Missense Mutation (SNP) | VAF 106/484 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.309); catalogued as rs1327519683; called by muse, mutect2, varscan2
- LCP1 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 113/277 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59939531; called by muse, mutect2, varscan2
- MAML3 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.221); catalogued as rs1002795255; called by muse, mutect2, varscan2
- MC2R | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 211/691 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV100563052, COSV59619684; called by muse, mutect2, varscan2
- MRPL43 | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.079); catalogued as rs374657325; called by muse, mutect2, varscan2
- MTTP | c.2048A>C p.E683A | Missense Mutation (SNP) | VAF 106/274 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55508310, COSV55509108; called by muse, mutect2, varscan2
- MUC4 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 112/300 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.65); catalogued as COSV100639614, COSV62200738; called by muse, mutect2, varscan2
- MYO6 | c.2302C>G p.Q768E | Missense Mutation (SNP) | VAF 36/503 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV100889336; called by muse, mutect2
- NT5E | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57628904; called by muse, mutect2
- OR2T12 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 135/476 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV100527946; called by muse, mutect2, varscan2
- PCCB | c.979C>A p.R327S | Missense Mutation (SNP) | VAF 117/457 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.026); catalogued as rs377660729; called by muse, mutect2, varscan2
- PCDH15 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 104/314 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV57314823; called by muse, mutect2, varscan2
- PCDHB13 | c.1353C>A p.F451L | Missense Mutation (SNP) | VAF 238/531 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53395076; called by muse, mutect2, varscan2
- PDK1 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1178133263, COSV56374117; called by muse, mutect2, varscan2
- PGM1 | c.1221G>T p.Q407H | Missense Mutation (SNP) | VAF 189/459 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV64300138; called by muse, mutect2, varscan2
- PIEZO2 | c.2623C>A p.Q875K | Missense Mutation (SNP) | VAF 234/802 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1251364710; called by muse, mutect2, varscan2
- PKD1 | c.12152G>C p.C4051S (on ENST00000262304 / NM_001009944.3; = p.C4050S on NM_000296.4) | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as rs753457784; called by muse, mutect2, varscan2
- PKM | c.804C>G p.I268M | Missense Mutation (SNP) | VAF 60/485 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV58790224; called by muse, mutect2, varscan2
- PPP1R10 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.155); catalogued as rs1470298322, COSV64740258; called by muse, mutect2, varscan2
- PPP1R21 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV54289438; called by muse, mutect2, varscan2
- PPP2R1A | c.754G>C p.A252P | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as COSV100436587; called by muse, mutect2, varscan2
- PRDM9 | c.24G>T p.E8D | Missense Mutation (SNP) | VAF 352/774 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.739); catalogued as COSV99689520; called by muse, varscan2
- PRKAR1B | c.891G>A p.E297= | Splice Region (SNP) | VAF 77/353 reads (22%) | catalogued as rs1381235500; called by muse, mutect2, varscan2
- PTPRZ1 | c.3632C>A p.T1211N | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs763005404; called by muse, mutect2, varscan2
- PTPRZ1 | c.6532G>A p.D2178N | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as COSV66432123; called by muse, mutect2
- RBM38 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 120/366 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as rs867171824, COSV100654875, COSV61133782; called by muse, mutect2, varscan2
- SCAF4 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1273742454, COSV99531995; called by muse, mutect2, varscan2
- SELENOS | c.514G>T p.G172* | Nonsense Mutation (SNP) | VAF 127/454 reads (28%) | catalogued as COSV68011244, COSV68011466; called by muse, mutect2, varscan2
- SHOX2 | c.796C>A p.P266T (on ENST00000441443 / NM_006884.3; = p.P290T on NM_003030.4) | Missense Mutation (SNP) | VAF 84/384 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs142921456, COSV67463402; called by muse, mutect2, varscan2
- SIRPB1 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs372469385; called by muse, mutect2, varscan2
- SLC12A8 | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 91/258 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58869548; called by muse, mutect2, varscan2
- SLC15A2 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 65/312 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55195814; called by muse, mutect2, varscan2
- SLC39A1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.374); catalogued as COSV57841816; called by muse, mutect2, varscan2
- SNAPC4 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs148417699; called by muse, mutect2, varscan2
- SNRNP27 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 141/467 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as rs1263500105; called by muse, mutect2, varscan2
- SYNM | c.689G>T p.C230F | Missense Mutation (SNP) | VAF 77/211 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs1203524814; called by muse, mutect2, varscan2
- THSD7A | c.4174G>C p.E1392Q | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.924); catalogued as COSV69855513, COSV69855590; called by muse, mutect2, varscan2
- TINAG | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1243682990; called by muse, varscan2
- TMEM132D | c.2985G>T p.M995I | Missense Mutation (SNP) | VAF 92/271 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV67162581, COSV67162646; called by muse, mutect2, varscan2
- TMEM71 | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 157/592 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.399); catalogued as rs1403552244; called by muse, mutect2, varscan2
- TSC2 | c.4013C>A p.S1338* | Nonsense Mutation (SNP) | VAF 94/233 reads (40%) | catalogued as COSV51917907; called by muse, mutect2, varscan2
- UNC80 | c.8345G>A p.R2782H | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs922116561; called by muse, mutect2
- VAV2 | c.2507C>T p.S836L (on ENST00000371850 / NM_001134398.2; = p.S797L on NM_003371.4) | Missense Mutation (SNP) | VAF 94/186 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs771858287; called by muse, varscan2
- ZNF761 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV61889589; called by muse, mutect2
- ACP6 | c.858G>T p.L286F | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ADAM29 | c.1923C>A p.H641Q | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- ADAMTSL4 | c.2546_2559del p.D849Vfs*46 | Frame Shift Del (DEL) | VAF 84/446 reads (19%) | called by mutect2, pindel, varscan2
- AGBL5 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 74/126 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ALG10B | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 104/424 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANAPC2 | c.2413G>T p.D805Y | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- APOBEC3F | c.134C>G p.S45* | Nonsense Mutation (SNP) | VAF 100/291 reads (34%) | called by muse, mutect2, varscan2
- ARMT1 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ASAP3 | c.1230dup p.S411Vfs*8 | Frame Shift Ins (INS) | VAF 54/118 reads (46%) | called by mutect2, pindel, varscan2
- ASCC3 | c.2813A>G p.K938R | Missense Mutation (SNP) | VAF 70/367 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASPM | c.9586C>G p.L3196V | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ASTN1 | c.3439G>C p.V1147L | Missense Mutation (SNP) | VAF 94/277 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ASTN1 | c.2017G>T p.D673Y | Missense Mutation (SNP) | VAF 100/369 reads (27%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- ATF1 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 59/292 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ATP5PF | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ATP6V0B | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- BBS12 | c.1894C>A p.P632T | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- BBS12 | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- BMT2 | c.921C>A p.Y307* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | called by muse, mutect2, varscan2
- BPIFC | c.880C>A p.H294N | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- C2CD5 | c.2169G>A p.Q723= | Splice Region (SNP) | VAF 34/188 reads (18%) | called by muse, mutect2, varscan2
- C7orf26 | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 121/310 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- CA10 | c.148T>C p.W50R | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1E | c.4557G>A p.M1519I | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC191 | c.1420G>T p.A474S | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCDC57 | c.1918G>T p.V640F | Missense Mutation (SNP) | VAF 91/184 reads (49%) | SIFT tolerated (0.69); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCNL1 | c.596A>G p.K199R | Missense Mutation (SNP) | VAF 175/400 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- CCT4 | c.458G>C p.R153P | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- CDC5L | c.2011C>G p.L671V | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CEP70 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 38/259 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHD2 | c.4108G>C p.D1370H | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CMYA5 | c.8283dup p.E2762Rfs*28 | Frame Shift Ins (INS) | VAF 47/162 reads (29%) | called by pindel, varscan2
- COL19A1 | c.1125dup p.G376Rfs*68 | Frame Shift Ins (INS) | VAF 31/239 reads (13%) | called by mutect2, pindel, varscan2
- COL4A3 | c.3767C>A p.P1256H | Missense Mutation (SNP) | VAF 93/317 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- COL5A2 | c.700G>T p.G234* | Nonsense Mutation (SNP) | VAF 70/293 reads (24%) | called by muse, mutect2, varscan2
- COLEC12 | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 103/392 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- COLEC12 | c.102G>T p.W34C | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRACD | c.1924C>A p.P642T | Missense Mutation (SNP) | VAF 57/434 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CSGALNACT1 | c.826T>A p.F276I | Missense Mutation (SNP) | VAF 161/401 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CSHL1 | c.157A>G p.T53A | Missense Mutation (SNP) | VAF 164/494 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CSPP1 | c.2848T>A p.S950T (on ENST00000676605; = p.S909T on NM_024790.6) | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CUL4A | c.1973G>A p.G658E (on ENST00000375440 / NM_001008895.4; = p.G558E on NM_003589.3) | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CUZD1 | c.227A>G p.Y76C | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- CYFIP1 | c.2563T>G p.Y855D | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIDO1 | c.1404G>C p.K468N | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DMTF1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 57/237 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DNAH10 | c.2805G>C p.K935N (on ENST00000409039; = p.K874N on NM_207437.3) | Missense Mutation (SNP) | VAF 81/147 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH11 | c.11926C>G p.L3976V | Missense Mutation (SNP) | VAF 62/278 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- DNAH3 | c.835C>A p.L279I | Missense Mutation (SNP) | VAF 96/224 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- DUSP12 | c.214G>T p.V72F | Missense Mutation (SNP) | VAF 81/276 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DZANK1 | c.1199G>C p.R400T (on ENST00000262547 / NM_001099407.1; = p.R201T on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF4A2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- EPHA3 | c.2899A>G p.S967G | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- EPHA5 | c.2167G>T p.G723C | Missense Mutation (SNP) | VAF 90/230 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); called by muse, varscan2
- F8 | c.1068G>C p.M356I | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- FAM160A2 | c.1436-1G>T p.X479_splice (on ENST00000449352 / NM_001098794.2; = p.X493_splice on NM_032127.4) | Splice Site (SNP) | VAF 60/138 reads (43%) | called by muse, mutect2, varscan2
- FAM187B | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 125/443 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FAM47C | c.1478C>A p.T493N | Missense Mutation (SNP) | VAF 145/260 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FCRL5 | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FLI1 | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNDC1 | c.1875del p.T626Pfs*14 | Frame Shift Del (DEL) | VAF 26/95 reads (27%) | called by mutect2, pindel, varscan2
- GANAB | c.1598C>G p.S533* | Nonsense Mutation (SNP) | VAF 69/116 reads (59%) | called by muse, mutect2, varscan2
- GNRHR | c.322T>C p.Y108H | Missense Mutation (SNP) | VAF 95/212 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGA4 | c.583-1G>T p.X195_splice | Splice Site (SNP) | VAF 62/136 reads (46%) | called by muse, mutect2, varscan2
- GPR89B | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by mutect2, varscan2
- GRM8 | c.1594del p.V532Sfs*33 | Frame Shift Del (DEL) | VAF 83/351 reads (24%) | called by mutect2, pindel, varscan2
- GSE1 | c.1774G>C p.D592H | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- HDAC7 | c.1630_1636del p.H544Afs*69 (on ENST00000427332; = p.H583Afs*69 on NM_015401.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 81/282 reads (29%) | called by mutect2, pindel, varscan2
- HELT | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 93/254 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HELZ2 | c.7464G>C p.E2488D (on ENST00000467148 / NM_001037335.2; = p.E1919D on NM_033405.3) | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, varscan2
- HOXD4 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 126/465 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IDUA | c.1747A>G p.I583V | Missense Mutation (SNP) | VAF 147/241 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGKV1D-42 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 120/509 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- ITGA3 | c.2939C>G p.S980W | Missense Mutation (SNP) | VAF 145/377 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ITPKC | c.1179G>C p.K393N | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2
- ITSN2 | c.4515C>G p.D1505E | Missense Mutation (SNP) | VAF 149/276 reads (54%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- KALRN | c.6384_6396del p.F2129Sfs*45 (on ENST00000360013 / NM_001024660.4; = p.F432Sfs*45 on NM_007064.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 110/337 reads (33%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.3883G>T p.D1295Y | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); called by muse, mutect2
- KIF20A | c.1665C>G p.I555M | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- KIR2DL4 | c.724C>T p.P242S (on ENST00000396284; = p.P203S on NM_001080770.2) | Missense Mutation (SNP) | VAF 123/449 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, varscan2
- LMAN1L | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- MAGEC2 | c.364dup p.E122Gfs*13 | Frame Shift Ins (INS) | VAF 69/137 reads (50%) | called by mutect2, pindel, varscan2
- MARK2 | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MDN1 | c.3497G>T p.R1166M | Missense Mutation (SNP) | VAF 119/407 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MFSD2A | c.433C>T p.L145F (on ENST00000372809 / NM_001136493.3; = p.L132F on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 2436/2842 reads (86%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- MICA | c.383G>T p.R128M | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- MROH2A | c.4095C>G p.I1365M | Missense Mutation (SNP) | VAF 86/262 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MROH2A | c.4361C>A p.T1454N | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- MRPL53 | c.215A>C p.H72P | Missense Mutation (SNP) | VAF 62/230 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MUC17 | c.8792C>A p.T2931K | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- MUC17 | c.12879G>C p.M4293I | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH1 | c.3921G>T p.R1307S | Missense Mutation (SNP) | VAF 74/381 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- MYH14 | c.4176G>T p.E1392D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- NEDD4 | c.3775G>C p.E1259Q (on ENST00000508342 / NM_001284338.1; = p.E840Q on NM_006154.4) | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NLRP9 | c.1240del p.D414Ifs*13 | Frame Shift Del (DEL) | VAF 53/222 reads (24%) | called by mutect2, pindel, varscan2
- NRSN1 | c.27del p.S10Pfs*64 | Frame Shift Del (DEL) | VAF 62/254 reads (24%) | called by mutect2, pindel, varscan2
- NUTM2G | c.1375C>A p.P459T | Missense Mutation (SNP) | VAF 78/261 reads (30%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- OLIG3 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 50/592 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR10A7 | c.721T>A p.C241S | Missense Mutation (SNP) | VAF 83/254 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2AJ1 | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- OR6B2 | c.471G>T p.M157I | Missense Mutation (SNP) | VAF 84/331 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PACC1 | c.157A>T p.S53C | Missense Mutation (SNP) | VAF 76/245 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- PCDH11Y | c.890G>T p.G297V (on ENST00000400457 / NM_032973.2; = p.G286V on NM_032971.3) | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PCDHB11 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 301/562 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGA7 | c.230T>A p.L77Q | Missense Mutation (SNP) | VAF 89/162 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCMTD1 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PDE3B | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- PDP2 | c.913C>A p.L305I | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PGA5 | c.827T>G p.V276G | Missense Mutation (SNP) | VAF 52/505 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PKD1 | c.11464G>C p.E3822Q (on ENST00000262304 / NM_001009944.3; = p.E3821Q on NM_000296.4) | Missense Mutation (SNP) | VAF 95/241 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- PKP3 | c.1526C>G p.S509C | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNLDC1 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 80/328 reads (24%) | called by muse, mutect2, varscan2
- POSTN | c.812T>C p.L271P | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PREX1 | c.4118C>G p.A1373G | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRKCSH | c.800C>G p.S267C | Missense Mutation (SNP) | VAF 106/311 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- PTPRO | c.1379A>G p.Y460C | Missense Mutation (SNP) | VAF 102/539 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- PTPRZ1 | c.2979T>A p.D993E | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- QSOX2 | c.302G>A p.W101* | Nonsense Mutation (SNP) | VAF 141/289 reads (49%) | called by muse, mutect2, varscan2
- RELN | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 102/357 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RERE | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 38/446 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2
- RHBDD3 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- RINL | c.50+3G>A | Splice Region (SNP) | VAF 41/182 reads (23%) | called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.226A>T p.I76F | Missense Mutation (SNP) | VAF 150/335 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SCN1A | c.2324C>A p.T775N (on ENST00000303395 / NM_001202435.3; = p.T764N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SELPLG | c.899C>A p.A300D | Missense Mutation (SNP) | VAF 113/264 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- SENP6 | c.2398G>C p.E800Q | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SH3KBP1 | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 87/165 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SHISA7 | c.1474T>C p.S492P | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- SLC27A5 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLCO4A1 | c.1109G>C p.R370T | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SLCO6A1 | c.656G>A p.S219N | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, varscan2
- SNIP1 | c.491G>C p.G164A | Missense Mutation (SNP) | VAF 102/208 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SPEG | c.9112A>G p.I3038V | Missense Mutation (SNP) | VAF 82/266 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SYNE1 | c.20420T>C p.L6807P (on ENST00000367255 / NM_182961.4; = p.L6736P on NM_033071.3) | Missense Mutation (SNP) | VAF 201/787 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TADA2B | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- TDRD15 | c.5225T>A p.V1742D | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- TESPA1 | c.305C>A p.A102E | Missense Mutation (SNP) | VAF 100/349 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TEX47 | c.406C>G p.H136D | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- THSD1 | c.1563G>C p.Q521H | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TMEM151A | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 178/283 reads (63%) | SIFT tolerated (0.28); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- TRAF3 | c.163A>T p.K55* | Nonsense Mutation (SNP) | VAF 199/388 reads (51%) | called by muse, mutect2, varscan2
- TRHDE | c.710A>G p.Y237C | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TTN | c.58871-1G>T p.X19624_splice (on ENST00000591111; = p.X12200_splice on NM_003319.4) | Splice Site (SNP) | VAF 95/265 reads (36%) | called by muse, mutect2, varscan2
- UBR4 | c.8277G>T p.Q2759H | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- UGT1A6 | c.727A>G p.I243V | Missense Mutation (SNP) | VAF 200/562 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- URAD | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 114/215 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- URAD | c.492C>A p.D164E | Missense Mutation (SNP) | VAF 116/220 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- USF3 | c.4413G>T p.Q1471H | Missense Mutation (SNP) | VAF 126/752 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.643); called by mutect2, varscan2
- USP40 | c.3481G>T p.G1161* | Nonsense Mutation (SNP) | VAF 105/376 reads (28%) | called by muse, mutect2, varscan2
- VIT | c.1933A>T p.R645* (on ENST00000389975 / NM_001177969.1; = p.R660* on NM_053276.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 178/334 reads (53%) | called by muse, mutect2, varscan2
- WDR45 | c.931G>A p.A311T (on ENST00000376372 / NM_001029896.2; = p.A312T on NM_007075.3) | Missense Mutation (SNP) | VAF 76/135 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- WDR6 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 92/169 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- XIRP2 | c.4139C>A p.T1380N (on ENST00000628543; = p.T1555N on NM_152381.6) | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XIRP2 | c.7682C>A p.S2561Y (on ENST00000628543; = p.S2736Y on NM_152381.6) | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFP69 | c.1036C>G p.H346D | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- ZNF281 | c.1601C>A p.A534D | Missense Mutation (SNP) | VAF 51/270 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF541 | c.3644G>C p.G1215A | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- ZNF551 | c.1209C>G p.I403M | Missense Mutation (SNP) | VAF 95/419 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ZNF585A | c.311A>G p.H104R (on ENST00000292841 / NM_001288800.2; = p.H49R on NM_152655.3) | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ZNF727 | c.1104C>A p.Y368* | Nonsense Mutation (SNP) | VAF 86/308 reads (28%) | called by muse, mutect2, varscan2
- ZNF85 | c.1715A>C p.D572A | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZYG11B | c.1275G>T p.Q425H | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- AHCTF1 | c.4920A>T p.P1640= (on ENST00000366508; = p.P1614= on NM_015446.5) | Silent (SNP) | VAF 83/330 reads (25%) | called by muse, mutect2, varscan2
- ALG1L2 | c.282G>A p.Q94= | Silent (SNP) | VAF 27/240 reads (11%) | catalogued as COSV70648952; called by muse, mutect2, varscan2
- ANKFY1 | c.2007C>A p.L669= (on ENST00000341657 / NM_001330063.2; = p.L670= on NM_016376.5) | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV100493273; called by muse, mutect2, varscan2
- ASPSCR1 | c.738G>T p.S246= | Silent (SNP) | VAF 37/64 reads (58%) | catalogued as COSV60731258; called by muse, mutect2, varscan2
- C6orf118 | c.381G>A p.P127= | Silent (SNP) | VAF 65/218 reads (30%) | catalogued as rs202048007, COSV100025130, COSV57816185; called by muse, mutect2, varscan2
- CADM3 | c.180G>T p.L60= (on ENST00000368125 / NM_001127173.3; = p.L94= on NM_021189.5) | Silent (SNP) | VAF 112/474 reads (24%) | called by muse, mutect2, varscan2
- CCT8 | c.1272A>G p.T424= | Silent (SNP) | VAF 69/177 reads (39%) | catalogued as rs1168620292; called by muse, mutect2, varscan2
- CDT1 | c.1509C>T p.S503= | Silent (SNP) | VAF 184/352 reads (52%) | catalogued as rs373408082; called by muse, mutect2, varscan2
- CDV3 | c.690T>G p.V230= | Silent (SNP) | VAF 37/215 reads (17%) | called by muse, mutect2, varscan2
- CECR2 | c.3144T>C p.D1048= (on ENST00000342247 / NM_001290047.2; = p.D864= on NM_001290046.1) | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as rs772411553; called by muse, mutect2, varscan2
- CEP70 | c.747G>T p.L249= | Silent (SNP) | VAF 38/262 reads (15%) | called by muse, mutect2, varscan2
- CRACD | c.1680C>A p.P560= | Silent (SNP) | VAF 149/207 reads (72%) | catalogued as rs565920613; called by muse, mutect2, varscan2
- CUX1 | c.2172C>G p.L724= | Silent (SNP) | VAF 41/434 reads (9%) | catalogued as COSV52902609; called by muse, mutect2
- EPHB3 | c.2976G>A p.Q992= | Silent (SNP) | VAF 37/264 reads (14%) | called by muse, mutect2, varscan2
- FGA | c.2322G>A p.G774= | Silent (SNP) | VAF 31/103 reads (30%) | called by muse, mutect2, varscan2
- GABRA6 | c.120T>A p.L40= | Silent (SNP) | VAF 202/423 reads (48%) | called by muse, mutect2, varscan2
- GOLGB1 | c.7911A>G p.K2637= | Silent (SNP) | VAF 52/186 reads (28%) | called by muse, mutect2, varscan2
- GRM1 | c.177C>A p.A59= | Silent (SNP) | VAF 134/383 reads (35%) | catalogued as COSV51395951; called by muse, mutect2, varscan2
- H3C12 | c.174G>T p.S58= | Silent (SNP) | VAF 72/153 reads (47%) | catalogued as rs1380699620; called by muse, mutect2, varscan2
- HECW2 | c.3495T>G p.R1165= | Silent (SNP) | VAF 55/229 reads (24%) | called by muse, mutect2, varscan2
- HELZ2 | c.6822G>A p.P2274= (on ENST00000467148 / NM_001037335.2; = p.P1705= on NM_033405.3) | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs201443242; called by muse, mutect2, varscan2
- HES3 | c.27C>A p.I9= | Silent (SNP) | VAF 189/298 reads (63%) | called by muse, mutect2, varscan2
- HEXB | c.1332C>T p.I444= | Silent (SNP) | VAF 154/377 reads (41%) | catalogued as rs762367349; called by muse, mutect2, varscan2
- HSPG2 | c.8355G>A p.P2785= | Silent (SNP) | VAF 127/256 reads (50%) | catalogued as rs371334604; called by muse, mutect2, varscan2
- IGLV1-36 | c.138C>T p.S46= | Silent (SNP) | VAF 96/280 reads (34%) | called by muse, mutect2, varscan2
- IQSEC3 | c.3099G>A p.A1033= (on ENST00000538872 / NM_001170738.2; = p.A730= on NM_015232.1) | Silent (SNP) | VAF 108/482 reads (22%) | catalogued as rs372435617; called by muse, mutect2, varscan2
- ITPRID1 | c.2901T>C p.N967= | Silent (SNP) | VAF 123/351 reads (35%) | called by muse, mutect2, varscan2
- KIAA1109 | c.6867G>A p.R2289= | Silent (SNP) | VAF 26/214 reads (12%) | catalogued as COSV52669606; called by muse, mutect2, varscan2
- KIR3DL1 | c.339G>A p.V113= | Silent (SNP) | VAF 60/188 reads (32%) | called by muse, mutect2, varscan2
- MFSD14B | c.609A>G p.T203= | Silent (SNP) | VAF 242/561 reads (43%) | called by muse, mutect2, varscan2
- MRC1 | c.4335G>A p.V1445= | Silent (SNP) | VAF 149/518 reads (29%) | catalogued as COSV53471134; called by muse, mutect2, varscan2
- MX2 | c.774G>A p.T258= | Silent (SNP) | VAF 44/236 reads (19%) | catalogued as rs746502416, COSV58097033; called by muse, mutect2, varscan2
- NMNAT3 | c.165G>A p.K55= (on ENST00000296202 / NM_001320512.1; = p.K18= on NM_178177.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/301 reads (5%) | called by muse, mutect2
- OR1J2 | c.897G>A p.E299= | Silent (SNP) | VAF 127/343 reads (37%) | catalogued as COSV58944846; called by muse, mutect2, varscan2
- OR2AJ1 | c.834T>C p.Y278= | Silent (SNP) | VAF 97/320 reads (30%) | called by muse, mutect2, varscan2
- OR2J1 | c.441G>C p.A147= | Silent (SNP) | VAF 82/181 reads (45%) | catalogued as COSV65850560, COSV65850623; called by muse, mutect2, varscan2
- PCLO | c.1446A>G p.Q482= | Silent (SNP) | VAF 204/811 reads (25%) | called by muse, mutect2, varscan2
- PLK1 | c.1122C>T p.L374= | Silent (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- PNLDC1 | c.1494G>A p.L498= | Silent (SNP) | VAF 113/293 reads (39%) | called by muse, mutect2, varscan2
- POU6F2 | c.819G>T p.P273= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as rs202064223; called by muse, mutect2, varscan2
- PSMD6 | c.708C>T p.L236= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV55759829; called by muse, mutect2, varscan2
- RPS3A | c.519C>T p.T173= | Silent (SNP) | VAF 64/278 reads (23%) | catalogued as rs11548525; called by muse, varscan2
- SELPLG | c.900C>G p.A300= | Silent (SNP) | VAF 114/267 reads (43%) | called by muse, mutect2, varscan2
- SERPINA11 | c.222C>T p.F74= | Silent (SNP) | VAF 36/204 reads (18%) | catalogued as rs1264237257, COSV58241513, COSV58242709; called by muse, mutect2, varscan2
- SLC16A10 | c.1017A>T p.S339= | Silent (SNP) | VAF 139/478 reads (29%) | called by muse, mutect2, varscan2
- SLC41A2 | c.288C>T p.A96= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs745917621; called by muse, mutect2, varscan2
- SLC4A2 | c.330G>T p.P110= | Silent (SNP) | VAF 34/170 reads (20%) | catalogued as COSV100055411, COSV59656475; called by muse, mutect2, varscan2
- SPI1 | c.288C>A p.L96= | Silent (SNP) | VAF 67/136 reads (49%) | catalogued as COSV57044755, COSV99909209; called by muse, mutect2, varscan2
- STRIP1 | c.957G>T p.P319= | Silent (SNP) | VAF 123/313 reads (39%) | called by muse, mutect2, varscan2
- TAF4B | c.852A>G p.Q284= | Silent (SNP) | VAF 90/282 reads (32%) | called by muse, mutect2, varscan2
- TAS2R40 | c.657T>A p.S219= | Silent (SNP) | VAF 34/249 reads (14%) | called by muse, mutect2, varscan2
- TBX18 | c.115C>A p.R39= | Silent (SNP) | VAF 76/268 reads (28%) | called by muse, mutect2
- TDO2 | c.54C>T p.L18= | Silent (SNP) | VAF 20/219 reads (9%) | catalogued as rs979088212, COSV72232692; called by muse, mutect2
- THAP7 | c.168G>C p.P56= | Silent (SNP) | VAF 25/335 reads (7%) | called by muse, mutect2
- TIGD5 | c.243C>T p.F81= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV57817361; called by muse, mutect2, varscan2
- TMEM214 | c.1839G>C p.L613= | Silent (SNP) | VAF 71/291 reads (24%) | catalogued as COSV99476358; called by muse, mutect2, varscan2
- TRIM51 | c.723T>C p.D241= | Silent (SNP) | VAF 75/207 reads (36%) | catalogued as rs775729772; called by muse, mutect2, varscan2
- TRIM66 | c.1176C>G p.P392= | Silent (SNP) | VAF 68/144 reads (47%) | catalogued as rs746401699; called by muse, mutect2, varscan2
- TTC28 | c.6204G>A p.A2068= | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as rs1459744941; called by muse, mutect2, varscan2
- TTC5 | c.1245G>T p.L415= | Silent (SNP) | VAF 62/153 reads (41%) | called by muse, mutect2, varscan2
- UBTF | c.1260G>A p.E420= | Silent (SNP) | VAF 50/314 reads (16%) | catalogued as rs527421287; called by muse, mutect2, varscan2
- WASHC2C | c.2511A>T p.T837= | Silent (SNP) | VAF 68/156 reads (44%) | called by mutect2, varscan2
- WDR17 | c.1158T>C p.F386= | Silent (SNP) | VAF 32/140 reads (23%) | catalogued as rs1019694423; called by muse, mutect2
- WNT16 | c.39C>T p.C13= | Silent (SNP) | VAF 52/137 reads (38%) | catalogued as rs748945275; called by muse, mutect2, varscan2
- XDH | c.771G>T p.L257= | Silent (SNP) | VAF 193/385 reads (50%) | called by muse, mutect2, varscan2
- ZBTB9 | c.255C>T p.L85= | Silent (SNP) | VAF 98/205 reads (48%) | catalogued as rs775340704, COSV67702197; called by muse, mutect2, varscan2
- ZFP37 | c.24G>A p.Q8= | Silent (SNP) | VAF 32/173 reads (18%) | called by muse, mutect2, varscan2
- ZNF546 | c.474A>G p.T158= | Silent (SNP) | VAF 47/169 reads (28%) | called by muse, mutect2, varscan2
- AC068473.1 | n.587G>A | RNA (SNP) | VAF 99/479 reads (21%) | called by muse, mutect2, varscan2
- AGMO | c.1263+58979C>G | Intron (SNP) | VAF 75/235 reads (32%) | catalogued as COSV61109304; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499100 G>A | 5'Flank (SNP) | VAF 54/141 reads (38%) | called by muse, mutect2, varscan2
- CACNA1D | c.1220+670G>T | Intron (SNP) | VAF 157/377 reads (42%) | called by muse, mutect2, varscan2
- CALU | c.*3370T>C | 3'UTR (SNP) | VAF 58/240 reads (24%) | called by muse, mutect2, varscan2
- CAPZA2 | c.506+10A>G | Intron (SNP) | VAF 49/127 reads (39%) | called by muse, mutect2, varscan2
- CLUH | c.2974+17G>C | Intron (SNP) | VAF 114/290 reads (39%) | called by muse, mutect2, varscan2
- DCHS2 | n.8012C>T | RNA (SNP) | VAF 58/179 reads (32%) | catalogued as rs769504815; called by muse, mutect2, varscan2
- DST | c.4297-4751T>C | Intron (SNP) | VAF 44/80 reads (55%) | called by muse, mutect2, varscan2
- DTYMK | c.240-1978G>A | Intron (SNP) | VAF 64/260 reads (25%) | catalogued as rs933012178; called by muse, mutect2, varscan2
- ETV1 | c.181+451A>G | Intron (SNP) | VAF 98/305 reads (32%) | called by muse, mutect2, varscan2
- FAT4 | c.5176-4821G>A | Intron (SNP) | VAF 54/183 reads (30%) | catalogued as rs1309082553; called by muse, mutect2, varscan2
- FCRL4 | c.1360+16T>C | Intron (SNP) | VAF 115/388 reads (30%) | called by muse, mutect2, varscan2
- GLI1 | c.-10C>G | 5'UTR (SNP) | VAF 12/399 reads (3%) | catalogued as COSV99954279; called by muse, mutect2
- GLOD4 | chr17:782594 G>C | 5'Flank (SNP) | VAF 21/241 reads (9%) | called by muse, mutect2
- GLOD4 | chr17:782690 G>C | 5'Flank (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100022450, COSV56752293; called by muse, varscan2
- IGFN1 | c.1241+345C>T | Intron (SNP) | VAF 68/203 reads (33%) | called by muse, mutect2, varscan2
- LINC01098 | n.778A>C | RNA (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- LINC01235 | n.383C>G | RNA (SNP) | VAF 76/304 reads (25%) | called by muse, mutect2, varscan2
- MEG3 | n.1040-1430T>C | Intron (SNP) | VAF 107/253 reads (42%) | called by muse, mutect2, varscan2
- MKS1 | c.749+24G>T | Intron (SNP) | VAF 149/488 reads (31%) | catalogued as rs1162677204; called by muse, mutect2, varscan2
- MSR1 | c.1033+2466G>A | Intron (SNP) | VAF 52/139 reads (37%) | catalogued as COSV50509409; called by muse, mutect2, varscan2
- NIPSNAP2 | c.*7A>G | 3'UTR (SNP) | VAF 66/204 reads (32%) | catalogued as rs777834456; called by muse, mutect2, varscan2
- NRG1 | c.502+31224C>T | Intron (SNP) | VAF 76/152 reads (50%) | called by muse, mutect2, varscan2
- PAK6 | c.-158T>G | 5'UTR (SNP) | VAF 87/274 reads (32%) | called by muse, mutect2, varscan2
- PALLD | c.*146G>A | 3'UTR (SNP) | VAF 100/358 reads (28%) | catalogued as rs1036505622; called by muse, mutect2, varscan2
- PDGFRA | c.629-22T>C | Intron (SNP) | VAF 93/908 reads (10%) | called by muse, mutect2, varscan2
- PLOD2 | c.1615-45A>T | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, varscan2
- PLPPR3 | c.658-19C>G | Intron (SNP) | VAF 46/92 reads (50%) | catalogued as rs915108784; called by muse, mutect2, varscan2
- PRCD | chr17:76544488 G>C | 3'Flank (SNP) | VAF 38/152 reads (25%) | called by muse, mutect2, varscan2
- PRDM9 | c.-38C>T | 5'UTR (SNP) | VAF 108/458 reads (24%) | called by muse, varscan2
- RAD21 | chr8:116874910 G>C | 5'Flank (SNP) | VAF 109/377 reads (29%) | called by muse, mutect2, varscan2
- REXO1L1P | n.55G>C | RNA (SNP) | VAF 79/1884 reads (4%) | called by muse, mutect2
- RNU6-1224P | chr8:102529365 G>A | 3'Flank (SNP) | VAF 11/109 reads (10%) | catalogued as rs1209022258; called by muse, mutect2, varscan2
- SATB2 | c.1174-20T>C | Intron (SNP) | VAF 126/409 reads (31%) | called by muse, mutect2, varscan2
- SLC22A23 | c.1703+37C>T | Intron (SNP) | VAF 46/318 reads (14%) | catalogued as rs1409491746; called by muse, mutect2, varscan2
- SLC9A9 | c.1470-33G>T | Intron (SNP) | VAF 227/567 reads (40%) | called by muse, mutect2, varscan2
- SMTN | c.-80-174G>A | Intron (SNP) | VAF 73/224 reads (33%) | catalogued as rs1252474611; called by muse, mutect2, varscan2
- TFAM | c.594+82G>A | Intron (SNP) | VAF 32/231 reads (14%) | called by muse, mutect2, varscan2
- TMEM135 | c.*6127C>G | 3'UTR (SNP) | VAF 86/188 reads (46%) | called by muse, mutect2, varscan2
- TSC2 | c.3884-70C>T | Intron (SNP) | VAF 18/56 reads (32%) | called by muse, varscan2
- TSC2 | c.3884-14C>G | Intron (SNP) | VAF 18/69 reads (26%) | called by muse, varscan2
- TULP3 | c.*1G>C | 3'UTR (SNP) | VAF 19/209 reads (9%) | called by muse, mutect2
